Somatic mutation profile of tumor specimen TCGA-2G-AAKL-01A (aliquot TCGA-2G-AAKL-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAKL, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 26.9 years (9,813 days).
Specimen TCGA-2G-AAKL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a3ff173-1451-45a3-a9cc-3b92e86ae1ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKL-10A (Blood Derived Normal), aliquot TCGA-2G-AAKL-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daf71fb1-6176-4db9-8f6c-9ddfeb2a4623

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, In Frame Del 1, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD6 | c.8144A>G p.N2715S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs1295592358; called by muse, mutect2, varscan2
- CHST2 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV58885711; called by muse, mutect2, varscan2
- KNTC1 | c.2020-1G>A p.X674_splice | Splice Site (SNP) | VAF 26/82 reads (32%) | catalogued as rs779604603; called by muse, mutect2, varscan2
- LRBA | c.1393A>C p.S465R | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs764124658; called by muse, mutect2, varscan2
- OR2A2 | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs139387901, COSV68872305; called by muse, mutect2, varscan2
- RP1L1 | c.7129G>A p.A2377T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs760896519; called by muse, mutect2, varscan2
- TNXB | c.8993C>T p.S2998L (on ENST00000647633; = p.S2751L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773291274; called by muse, mutect2, varscan2
- YKT6 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as rs775371239; called by muse, mutect2, varscan2
- ARID5B | c.450_456del p.L151Vfs*24 | Frame Shift Del (DEL) | VAF 39/79 reads (49%) | called by mutect2, pindel, varscan2
- MYCN | c.1155C>A p.N385K | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PPP1R36 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCIN | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- SLC52A2 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STC1 | c.621_637delinsTG p.R208_R213delinsG | In Frame Del (DEL) | VAF 44/203 reads (22%) | called by pindel, varscan2*
- VPS13B | c.3598C>G p.R1200G | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MORC3 | chr21:36320196 C>T | 5'Flank (SNP) | VAF 28/62 reads (45%) | catalogued as rs536827119; called by muse, mutect2, varscan2
